Somatic mutation profile of tumor specimen TCGA-FK-A3SE-01A (aliquot TCGA-FK-A3SE-01A-11D-A22D-08) from TCGA case TCGA-FK-A3SE, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.4 years (11,472 days).
Specimen TCGA-FK-A3SE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a81a9d3-32ef-4d18-aee9-b3d87a1f8f77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A3SE-10A (Blood Derived Normal), aliquot TCGA-FK-A3SE-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bd6b51f-a172-42a5-a545-d9882c0c76e0

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC1A6 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs772999168, COSV55669463; called by muse, mutect2, varscan2
- SLC12A4 | c.732G>A p.S244= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as rs372226074, COSV57927750; called by muse, mutect2, varscan2
- TMEM250 | c.87C>T p.R29= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV69307517; called by mutect2, varscan2
- ZCCHC10 | c.360C>T p.A120= (on ENST00000509437 / NM_001300818.3; = p.A98= on NM_017665.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as COSV60772626; called by muse, mutect2, varscan2
- LRRFIP1 | c.748-1302G>T | Intron (SNP) | VAF 57/139 reads (41%) | catalogued as COSV55250472, COSV55250815; called by muse, mutect2, varscan2
